Somatic mutation profile of tumor specimen TCGA-DX-A7ER-01A (aliquot TCGA-DX-A7ER-01A-11D-A36J-09) from TCGA case TCGA-DX-A7ER, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 69.4 years (25,363 days).
Specimen TCGA-DX-A7ER-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 891bf7e0-2382-44f9-8a94-2c16e124a020.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A7ER-10A (Blood Derived Normal), aliquot TCGA-DX-A7ER-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab0cf521-8307-4a92-af06-4b2a5d117d9c

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 2, 3'Flank 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.1065T>G p.Y355* | Nonsense Mutation (SNP) | VAF 31/58 reads (53%) | catalogued as COSV100249944; called by muse, mutect2, varscan2
- CACNA1A | c.2375C>G p.A792G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100800273; called by muse, mutect2, varscan2
- COLGALT1 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375611652; called by muse, mutect2, varscan2
- DERA | c.875C>T p.T292I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV101397265; called by muse, mutect2, varscan2
- GPM6A | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1049820, COSV99702056; called by muse, mutect2, varscan2
- NPAS4 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV60649858; called by muse, mutect2, varscan2
- OR10C1 | c.670G>T p.V224F (on ENST00000622521; = p.V222F on NM_013941.3) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.157); catalogued as COSV101010780, COSV101010899; called by muse, mutect2, varscan2
- PCDH11Y | c.629T>A p.L210Q (on ENST00000400457 / NM_032973.2; = p.L199Q on NM_032971.3) | Missense Mutation (SNP) | VAF 93/96 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99290249; called by muse, mutect2, varscan2
- ROBO2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1196957436, COSV59895199; called by muse, mutect2, varscan2
- RXFP2 | c.881G>T p.G294V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as COSV100033871; called by muse, mutect2, varscan2
- SLC26A6 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100257919; called by muse, mutect2, varscan2
- SLC44A3 | c.1186G>C p.A396P (on ENST00000271227 / NM_001114106.3; = p.A348P on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99597701; called by muse, mutect2
- SNX33 | c.978C>G p.Y326* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100145697, COSV100145751; called by muse, mutect2, varscan2
- TCHH | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1207152589, COSV64275116; called by muse, mutect2, varscan2
- TMEM74 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99865225; called by muse, mutect2, varscan2
- TRPC7 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61460668; called by muse, mutect2, varscan2
- MED21 | c.86_111del p.C29Yfs*6 | Frame Shift Del (DEL) | VAF 39/76 reads (51%) | called by mutect2, pindel, varscan2
- LAMB1 | c.2100G>A p.L700= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV99739559, COSV99740111; called by muse, mutect2, varscan2
- MUC5B | c.6303C>T p.T2101= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as rs746289984, COSV101499948; called by muse, mutect2, varscan2
- OBSCN | c.11724C>A p.T3908= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1421629675, COSV99470893; called by muse, mutect2, varscan2
- TMEM94 | c.561C>T p.I187= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV100050002; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73700947 del CCCA | 3'Flank (DEL) | VAF 22/39 reads (56%) | called by mutect2, pindel, varscan2
- OR2H2 | chr6:29582309 C>G | 5'Flank (SNP) | VAF 55/121 reads (45%) | catalogued as COSV100589361; called by muse, mutect2, varscan2
